Somatic mutation profile of tumor specimen ALCH-B25W-TTP1-A (aliquot ALCH-B25W-TTP1-A-2-0-D-A774-36) from ALCHEMIST case ALCH-B25W, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.2 years (25,658 days).
Specimen ALCH-B25W-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76b7ad1b-c2d6-4972-826e-6e3761e75f04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B25W-NB1-A (Blood Derived Normal), aliquot ALCH-B25W-NB1-A-1-0-D-A774-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ac91784-774a-4a32-a13e-b52787afd3ee

The open-access MAF lists 380 somatic variants for this specimen: 247 protein-altering or splice-affecting, 82 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 218, Silent 82, Intron 29, Nonsense Mutation 17, Splice Site 8, 5'UTR 7, RNA 7, 5'Flank 6, Frame Shift Del 2, Splice Region 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLN8 | c.283A>T p.K95* | Nonsense Mutation (SNP) | VAF 93/497 reads (19%) | catalogued as rs759830733; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 57/294 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 15/399 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV51055694; called by muse, mutect2
- ADAMTS7 | c.3863G>T p.G1288V | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV66307274; called by muse, mutect2, varscan2
- AGRN | c.1885G>T p.G629C | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs150061172; called by muse, mutect2, varscan2
- AKAP4 | c.2516G>A p.G839E | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1269014457, COSV62073821; called by muse, mutect2, varscan2
- AKAP9 | c.1357A>G p.I453V | Missense Mutation (SNP) | VAF 105/924 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs1201114363; called by muse, varscan2
- ALG6 | c.707G>A p.C236Y | Missense Mutation (SNP) | VAF 68/892 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.056); catalogued as rs771479098; called by muse, mutect2
- AMPH | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 27/369 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1465052975; called by muse, mutect2
- ARPP21 | c.1149T>A p.S383R | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV104386469; called by muse, mutect2
- ASTN1 | c.2803A>G p.S935G | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as rs1373672296; called by muse, mutect2
- ATP2B4 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs369212336; called by muse, mutect2
- ATXN7L3B | c.156G>C p.E52D | Missense Mutation (SNP) | VAF 54/779 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV72966221; called by muse, mutect2
- BRD8 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 69/409 reads (17%) | catalogued as COSV50148008; called by muse, mutect2, varscan2
- CACNA1I | c.2446C>T p.Q816* | Nonsense Mutation (SNP) | VAF 7/129 reads (5%) | catalogued as rs1420183550; called by muse, mutect2
- CEP95 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 23/226 reads (10%) | catalogued as rs575763735; called by muse, mutect2
- CHL1 | c.3496G>C p.E1166Q (on ENST00000397491 / NM_001253387.1; = p.E1182Q on NM_006614.4) | Missense Mutation (SNP) | VAF 71/411 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.293); catalogued as COSV56601533; called by muse, mutect2, varscan2
- COL1A2 | c.3019G>A p.D1007N | Missense Mutation (SNP) | VAF 79/699 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs779934676, COSV51958830; called by muse, mutect2, varscan2
- COL3A1 | c.3363A>G p.P1121= | Splice Region (SNP) | VAF 34/448 reads (8%) | catalogued as rs1241634666; called by muse, mutect2
- CRACD | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 23/346 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1481842908, COSV51720509; called by muse, mutect2
- CTSG | c.78G>T p.E26D | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1180061812; called by muse, varscan2
- CYP2A7 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99393635; called by muse, mutect2
- CYP4A11 | c.180C>A p.F60L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV60222221; called by muse, mutect2, varscan2
- DAAM2 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs780707234; called by muse, mutect2
- DNAH6 | c.1762G>C p.E588Q | Missense Mutation (SNP) | VAF 34/560 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV52879330, COSV99409129; called by muse, mutect2
- DPPA4 | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 48/516 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.446); catalogued as rs200311182; called by muse, mutect2
- ESF1 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 18/664 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs931351296; called by muse, mutect2
- FAM160A2 | c.1936G>T p.A646S (on ENST00000449352 / NM_001098794.2; = p.A660S on NM_032127.4) | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1272513162; called by muse, mutect2, varscan2
- FAM170A | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV58927270; called by muse, mutect2, varscan2
- FIBCD1 | c.886T>C p.F296L | Missense Mutation (SNP) | VAF 58/302 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as rs1349248327; called by muse, mutect2, varscan2
- FUT9 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 33/297 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.03); catalogued as COSV56157559; called by muse, mutect2, varscan2
- GABRR1 | c.1211G>C p.G404A | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1220181292; called by muse, mutect2
- GLIPR1L2 | c.262G>C p.A88P | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57556296; called by muse, mutect2, varscan2
- GPC5 | c.786A>C p.Q262H | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65602029; called by muse, mutect2, varscan2
- GPX5 | c.303C>A p.C101* | Nonsense Mutation (SNP) | VAF 40/415 reads (10%) | catalogued as COSV69079462; called by muse, mutect2
- GRIN3A | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.235); catalogued as rs1038159150; called by muse, mutect2, varscan2
- GTPBP4 | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100672750; called by muse, mutect2, varscan2
- GUCY1A2 | c.1663C>A p.H555N | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.296); catalogued as COSV56483797; called by muse, mutect2
- IGHV3-13 | c.341G>A p.C114Y | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1555437043; called by muse, mutect2
- JAKMIP3 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 72/514 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771196879; called by muse, mutect2, varscan2
- KALRN | c.7891G>T p.D2631Y (on ENST00000360013 / NM_001024660.4; = p.D934Y on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/334 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52258370; called by muse, mutect2, varscan2
- KLKB1 | c.747C>G p.I249M | Missense Mutation (SNP) | VAF 71/610 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.384); catalogued as rs757891885, COSV52993760; called by muse, mutect2, varscan2
- KRTAP6-1 | c.24C>A p.N8K | Missense Mutation (SNP) | VAF 16/218 reads (7%) | PolyPhen possibly damaging (0.586); catalogued as COSV100228842; called by muse, mutect2
- LRP1B | c.10161T>A p.D3387E | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748486357; called by muse, mutect2
- LRP6 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 49/459 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV53788673; called by muse, mutect2, varscan2
- MACF1 | c.18929G>T p.W6310L (on ENST00000372915; = p.W4355L on NM_012090.5) | Missense Mutation (SNP) | VAF 54/675 reads (8%) | catalogued as COSV99244578; called by muse, mutect2
- MAP7D3 | c.1745A>G p.Y582C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV60170117; called by mutect2, varscan2
- MMP16 | c.872-1G>C p.X291_splice | Splice Site (SNP) | VAF 14/122 reads (11%) | catalogued as rs1554578890, COSV99686299; called by muse, mutect2, varscan2
- MMRN2 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs980698473; called by muse, mutect2, varscan2
- MYF6 | c.275C>A p.T92N | Missense Mutation (SNP) | VAF 68/590 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV57353177; called by muse, mutect2, varscan2
- NHEJ1 | c.390+1G>T p.X130_splice | Splice Site (SNP) | VAF 44/403 reads (11%) | catalogued as CS162311; called by muse, mutect2, varscan2
- NKAPL | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV59198000; called by muse, mutect2
- OR2A14 | c.282T>A p.F94L | Missense Mutation (SNP) | VAF 21/249 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV68717976; called by muse, mutect2
- OR2H2 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs572286350; called by muse, mutect2
- OR2L13 | c.320C>A p.A107E | Missense Mutation (SNP) | VAF 33/646 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV63553896; called by muse, mutect2
- OR2M5 | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as COSV63545767; called by muse, mutect2
- OR2W3 | c.797C>A p.S266Y | Missense Mutation (SNP) | VAF 64/476 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV64456921; called by muse, mutect2
- OR4A5 | c.697G>C p.A233P | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100157365; called by muse, varscan2
- OR4D11 | c.762C>A p.C254* | Nonsense Mutation (SNP) | VAF 32/362 reads (9%) | catalogued as rs1208188813; called by muse, mutect2
- OR6C75 | c.316G>T p.G106W | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs760730475; called by muse, mutect2, varscan2
- OR6X1 | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60010280; called by muse, mutect2
- PACS1 | c.1811C>T p.S604F | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs747956650, COSV57698834; called by muse, mutect2, varscan2
- PADI3 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs998243849; called by muse, mutect2, varscan2
- PAPPA2 | c.1795G>T p.E599* | Nonsense Mutation (SNP) | VAF 12/183 reads (7%) | catalogued as COSV62786457; called by muse, mutect2
- PCDH10 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52088455; called by muse, mutect2
- PHACTR3 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 10/150 reads (7%) | catalogued as COSV63025673; called by muse, mutect2
- PLEKHA4 | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs752370095; called by muse, mutect2
- PLEKHA5 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54703899, COSV54712529; called by muse, mutect2
- PLXNA4 | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 43/503 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs1286851918; called by muse, mutect2
- PLXNA4 | c.1803G>T p.M601I | Missense Mutation (SNP) | VAF 44/501 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV58127276; called by muse, mutect2
- POTEF | c.474C>G p.I158M | Missense Mutation (SNP) | VAF 86/353 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.724); catalogued as rs759769429, COSV62544865; called by muse, mutect2, varscan2
- PRDM16 | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 45/395 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs1173816589, COSV54595618, COSV54614301; called by muse, mutect2, varscan2
- PTGIR | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1251955693; called by muse, mutect2, varscan2
- PTPRT | c.1703C>A p.A568D | Missense Mutation (SNP) | VAF 43/348 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV61998468; called by muse, mutect2, varscan2
- RFX6 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 38/300 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100264263, COSV60587617; called by muse, mutect2, varscan2
- RUBCNL | c.1957C>T p.L653F | Missense Mutation (SNP) | VAF 48/377 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as rs1195244105, COSV99060258; called by muse, mutect2, varscan2
- RYR1 | c.4645C>A p.P1549T | Missense Mutation (SNP) | VAF 68/648 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62093801; called by muse, mutect2
- SALL2 | c.2386A>G p.I796V | Missense Mutation (SNP) | VAF 95/567 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs912415442; called by muse, mutect2, varscan2
- SERPINB4 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.033); catalogued as rs750116682, COSV61984264; called by muse, mutect2
- SFTPD | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 19/364 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100954582; called by muse, mutect2
- SLC49A3 | c.1426G>A p.G476R (on ENST00000404286 / NM_001294341.2; = p.G475R on NM_032219.4) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.047); catalogued as rs1195171622; called by muse, mutect2, varscan2
- ST8SIA2 | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 33/290 reads (11%) | PolyPhen possibly damaging (0.842); catalogued as COSV51568153; called by muse, mutect2, varscan2
- SYNPO2L | c.2069T>C p.V690A (on ENST00000394810 / NM_001114133.3; = p.V466A on NM_024875.5) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1477710940; called by mutect2, varscan2
- TECPR1 | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs375317554; called by muse, mutect2, varscan2
- TEX55 | c.1319T>G p.F440C | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.54); catalogued as COSV55210740; called by muse, mutect2, varscan2
- TGFBR3 | c.2167-1G>A p.X723_splice | Splice Site (SNP) | VAF 85/696 reads (12%) | catalogued as rs778423101; called by muse, mutect2, varscan2
- TPTE2 | c.500G>T p.R167M | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV99691204; called by muse, mutect2, varscan2
- TRIML1 | c.645G>T p.E215D | Missense Mutation (SNP) | VAF 65/410 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV60194322; called by muse, mutect2, varscan2
- TRPV3 | c.104C>A p.T35N | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs751015109; called by muse, varscan2
- TSHZ2 | c.401C>A p.S134* | Nonsense Mutation (SNP) | VAF 18/165 reads (11%) | catalogued as COSV100295252, COSV61589386; called by muse, mutect2, varscan2
- WFS1 | c.2190G>C p.W730C | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766073085, COSV99901523; called by muse, mutect2, varscan2
- ZFHX4 | c.6190C>A p.P2064T | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV50803953; called by muse, mutect2, varscan2
- ZNF574 | c.2632G>C p.V878L | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55905966; called by muse, mutect2, varscan2
- ZNF582 | c.1371G>C p.E457D | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV56731607; called by muse, mutect2, varscan2
- ABCD3 | c.1223G>T p.R408L | Missense Mutation (SNP) | VAF 62/809 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- AC093791.1 | n.466-2A>C | Splice Site (SNP) | VAF 53/231 reads (23%) | called by muse, mutect2, varscan2
- ACTN4 | c.1803C>G p.N601K | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.063); called by muse, mutect2
- ADAM19 | c.1129G>T p.G377W | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4489G>T p.V1497L | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.138); called by muse, mutect2
- ADCK1 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- ADCY1 | c.1321A>C p.T441P | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- AKAP6 | c.6185A>T p.E2062V | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AMMECR1 | c.527T>C p.I176T | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANTXR1 | c.415T>A p.Y139N | Missense Mutation (SNP) | VAF 48/670 reads (7%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.943); called by muse, mutect2
- ARFGEF2 | c.3198G>C p.Q1066H | Missense Mutation (SNP) | VAF 58/774 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ASMTL | c.1122C>A p.H374Q | Missense Mutation (SNP) | VAF 42/390 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ATF6B | c.1858G>A p.V620M | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AXDND1 | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 68/423 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- BARX2 | c.287C>A p.A96E | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- BCL11A | c.2033G>T p.G678V (on ENST00000335712 / NM_001365609.1; = p.G712V on NM_018014.4) | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CALB2 | c.386C>A p.A129D | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, varscan2
- CCDC74A | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- CCKBR | c.1144T>A p.S382T | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCN1 | c.719C>G p.S240* | Nonsense Mutation (SNP) | VAF 68/756 reads (9%) | called by muse, mutect2
- CCSER1 | c.2386G>T p.D796Y | Missense Mutation (SNP) | VAF 39/349 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CD163 | c.2961del p.T988Lfs*9 | Frame Shift Del (DEL) | VAF 77/625 reads (12%) | called by mutect2, pindel, varscan2
- CDC23 | c.1324T>A p.C442S | Missense Mutation (SNP) | VAF 55/357 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- CDH10 | c.1505G>T p.R502I | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CELF2 | c.1049G>C p.G350A (on ENST00000416382 / NM_001025077.3; = p.G357A on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/418 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- CKAP2L | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 183/1167 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLDN34 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CNGB1 | c.2008A>C p.N670H | Missense Mutation (SNP) | VAF 25/419 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CNGB3 | c.1243C>A p.Q415K | Missense Mutation (SNP) | VAF 56/387 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CNOT2 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 51/396 reads (13%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); called by muse, varscan2
- COL20A1 | c.2260C>A p.P754T | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CR1 | c.6002+2T>G p.X2001_splice | Splice Site (SNP) | VAF 26/286 reads (9%) | called by muse, mutect2
- CSMD3 | c.5326C>T p.P1776S (on ENST00000297405 / NM_001363185.1; = p.P1672S on NM_052900.3) | Missense Mutation (SNP) | VAF 19/428 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2
- CTTNBP2 | c.1419T>A p.D473E | Missense Mutation (SNP) | VAF 55/729 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- CYP2A13 | c.90G>T p.R30S | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- DBR1 | c.311T>C p.I104T | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- DCLK1 | c.1390G>T p.V464F | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DEPP1 | c.581G>C p.R194P | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DLG3 | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DLGAP3 | c.619G>C p.G207R | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- DNAH3 | c.4739A>T p.Q1580L | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.232); called by muse, mutect2
- EPHA7 | c.1669A>T p.I557F | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.529); called by muse, mutect2
- EPHA7 | c.515G>T p.R172I | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERICH3 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 28/552 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FAT4 | c.14268G>T p.K4756N | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.165); called by muse, mutect2
- FUBP1 | c.1925A>T p.Q642L | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- GABRG1 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GAPVD1 | c.4318T>A p.S1440T (on ENST00000394104; = p.S1449T on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- GLRX3 | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 28/461 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2
- GRIA3 | c.690G>T p.L230F | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GYS2 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 28/928 reads (3%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.961); called by muse, mutect2
- HDAC9 | c.281A>T p.K94I | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HHIPL1 | c.479A>C p.Y160S | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HNF4A | c.23T>G p.V8G | Missense Mutation (SNP) | VAF 24/584 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); called by muse, mutect2
- INTS4 | c.610T>C p.F204L | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IRS4 | c.1292G>T p.S431I | Missense Mutation (SNP) | VAF 84/351 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ITGB7 | c.1835T>C p.L612P | Missense Mutation (SNP) | VAF 48/457 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- KCNA1 | c.979G>C p.G327R | Missense Mutation (SNP) | VAF 42/370 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KIF16B | c.2803C>A p.P935T | Missense Mutation (SNP) | VAF 38/646 reads (6%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.05); called by muse, mutect2
- KIR3DL2 | c.557T>C p.M186T | Missense Mutation (SNP) | VAF 75/1033 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- KLHL2 | c.793G>T p.V265F | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- KLKB1 | c.488+1G>T p.X163_splice | Splice Site (SNP) | VAF 49/475 reads (10%) | called by muse, mutect2, varscan2
- LMO1 | c.433G>C p.G145R | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.211); called by muse, mutect2
- LPAR5 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LTA | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 27/380 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2
- LZTS3 | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.158); called by muse, mutect2
- MED13L | c.755A>T p.E252V | Missense Mutation (SNP) | VAF 64/706 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.307); called by muse, mutect2
- MEFV | c.2231C>A p.A744D | Missense Mutation (SNP) | VAF 54/582 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2
- MERTK | c.2134G>T p.E712* | Nonsense Mutation (SNP) | VAF 162/1126 reads (14%) | called by muse, mutect2, varscan2
- METTL15 | c.435G>T p.Q145H | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2
- MFSD2A | c.1117G>A p.V373I (on ENST00000372809 / NM_001136493.3; = p.V360I on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.406); called by muse, mutect2
- MGMT | c.481G>T p.V161L (on ENST00000306010; = p.V130L on NM_002412.5) | Missense Mutation (SNP) | VAF 38/291 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MIS18BP1 | c.1238G>A p.W413* | Nonsense Mutation (SNP) | VAF 25/302 reads (8%) | called by muse, mutect2
- MS4A12 | c.709G>C p.V237L | Missense Mutation (SNP) | VAF 16/271 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2
- MUC13 | c.1048C>A p.L350M | Missense Mutation (SNP) | VAF 49/662 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.835); called by muse, mutect2
- MYH9 | c.1808C>A p.S603Y | Missense Mutation (SNP) | VAF 25/720 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYLK | c.4154G>T p.R1385L | Missense Mutation (SNP) | VAF 26/480 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- NAA11 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 14/445 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2
- NLGN2 | c.1313G>T p.W438L | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLGN2 | c.1314G>T p.W438C | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPHS2 | c.294A>T p.L98F | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2
- NSUN7 | c.811A>T p.K271* | Nonsense Mutation (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- OR51E2 | c.896G>T p.R299I | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2
- OR5T1 | c.665C>G p.T222S | Missense Mutation (SNP) | VAF 50/339 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- OR6X1 | c.758T>A p.V253D | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); called by muse, mutect2
- PALM2AKAP2 | c.1237G>T p.G413W (on ENST00000259318 / NM_001136562.3; = p.G644W on NM_007203.5) | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- PHF11 | c.584T>A p.M195K | Missense Mutation (SNP) | VAF 106/612 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PLAA | c.638G>C p.S213T | Missense Mutation (SNP) | VAF 33/334 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLCH1 | c.4050_4051del p.C1351Ffs*12 (on ENST00000340059 / NM_001130960.2; = p.C1343Ffs*12 on NM_014996.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 44/279 reads (16%) | called by pindel, varscan2
- PLCL2 | c.1885C>G p.Q629E (on ENST00000615277 / NM_001144382.2; = p.Q503E on NM_015184.5) | Missense Mutation (SNP) | VAF 15/372 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.012); called by muse, mutect2
- PNPLA6 | c.676G>T p.G226C (on ENST00000414982 / NM_001166111.2; = p.G178C on NM_006702.5) | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PRKACB | c.181G>C p.V61L | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- PRTG | c.3180G>C p.K1060N | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PRUNE2 | c.6713C>T p.T2238I | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RAB38 | c.464G>A p.W155* | Nonsense Mutation (SNP) | VAF 29/120 reads (24%) | called by mutect2, varscan2
- RAB40AL | c.224G>T p.R75I | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RAI1 | c.1822G>T p.A608S | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- RANBP2 | c.5438C>G p.P1813R | Missense Mutation (SNP) | VAF 56/746 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); called by muse, mutect2
- RASGEF1C | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, varscan2
- RASGEF1C | c.118T>C p.S40P | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- RASGRP3 | c.1499T>C p.M500T (on ENST00000402538 / NM_001349975.2; = p.M499T on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- RBM48 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 30/307 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.38); called by muse, mutect2
- RGPD3 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 58/1058 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2
- RGPD4 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, varscan2
- ROBO4 | c.1805C>A p.P602Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, varscan2
- SCYL3 | c.34A>G p.T12A | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SHPRH | c.36G>T p.R12S | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SLC22A16 | c.1528G>T p.V510F | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLC25A53 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- SLC6A14 | c.1643T>C p.F548S | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- SLC6A17 | c.1903G>C p.V635L | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- SLC9A9 | c.457-1G>C p.X153_splice | Splice Site (SNP) | VAF 30/496 reads (6%) | called by muse, mutect2
- SUPT6H | c.512A>C p.E171A | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TANGO6 | c.608T>G p.L203R | Missense Mutation (SNP) | VAF 27/535 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- TBR1 | c.1676G>A p.G559D | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TEC | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 19/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TEX55 | c.1032C>G p.D344E | Missense Mutation (SNP) | VAF 28/412 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.41); called by muse, mutect2
- TIGD1 | c.608C>G p.A203G | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.694); called by muse, mutect2
- TMEM92 | c.171-2A>T p.X57_splice | Splice Site (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- TNFRSF4 | c.540G>T p.Q180H | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- TNN | c.1711C>G p.Q571E | Missense Mutation (SNP) | VAF 51/694 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.142); called by muse, mutect2
- TRPC5 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSPAN12 | c.287A>T p.Y96F | Missense Mutation (SNP) | VAF 54/649 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); called by muse, mutect2
- TTN | c.63548C>A p.A21183E (on ENST00000591111; = p.A13759E on NM_003319.4) | Missense Mutation (SNP) | VAF 10/252 reads (4%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- TTN | c.34058A>T p.E11353V (on ENST00000591111; = p.E10426V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/476 reads (13%) | PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- TTR | c.359C>A p.S120Y | Missense Mutation (SNP) | VAF 179/829 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TUBGCP2 | c.1079A>T p.H360L | Missense Mutation (SNP) | VAF 38/288 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- TUBGCP5 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.107); called by mutect2, varscan2
- TXK | c.1316T>A p.L439H | Missense Mutation (SNP) | VAF 15/246 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- TXLNB | c.257G>T p.S86I | Missense Mutation (SNP) | VAF 84/435 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- UEVLD | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2
- UGT1A8 | c.131T>A p.V44E | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- UPK2 | c.345C>A p.F115L | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VLDLR | c.660C>A p.D220E | Missense Mutation (SNP) | VAF 15/402 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2
- VXN | c.592G>T p.G198* | Nonsense Mutation (SNP) | VAF 27/146 reads (18%) | called by muse, mutect2, varscan2
- WDR3 | c.2620G>T p.V874L | Missense Mutation (SNP) | VAF 24/305 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- WDR76 | c.1225T>G p.F409V | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, varscan2
- WDR77 | c.89A>C p.Q30P | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); called by muse, mutect2
- ZBTB14 | c.881A>G p.K294R | Missense Mutation (SNP) | VAF 73/574 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZFHX4 | c.5558C>A p.P1853Q | Missense Mutation (SNP) | VAF 50/466 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFYVE26 | c.2395A>T p.T799S | Missense Mutation (SNP) | VAF 153/730 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ZGRF1 | c.2150G>T p.G717V | Missense Mutation (SNP) | VAF 21/336 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.063); called by muse, mutect2
- ZIC1 | c.666G>C p.K222N | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- ZNF217 | c.1886G>T p.R629I | Missense Mutation (SNP) | VAF 58/640 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.243); called by muse, mutect2
- ZNF329 | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ZNF469 | c.7569G>T p.Q2523H (on ENST00000437464; = p.Q2551H on NM_001367624.2) | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ZNF521 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 13/308 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- ZNF582 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 16/414 reads (4%) | called by muse, mutect2
- ZNF592 | c.1345G>T p.D449Y | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ZNF729 | c.1830C>A p.N610K | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ZNF786 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 18/125 reads (14%) | called by muse, mutect2
- ZNF805 | c.17C>A p.T6K | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- ZNF91 | c.2228A>T p.K743M | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACTN2 | c.2565C>A p.P855= | Silent (SNP) | VAF 59/360 reads (16%) | called by muse, mutect2, varscan2
- ADCY1 | c.1320C>T p.I440= | Silent (SNP) | VAF 24/189 reads (13%) | called by muse, mutect2, varscan2
- AHNAK2 | c.2442G>A p.R814= | Silent (SNP) | VAF 141/740 reads (19%) | called by muse, mutect2, varscan2
- AKAP9 | c.1890A>G p.L630= | Silent (SNP) | VAF 43/404 reads (11%) | catalogued as rs200976922; ClinVar: likely benign; called by muse, mutect2
- ANO6 | c.2055A>T p.P685= | Silent (SNP) | VAF 74/477 reads (16%) | called by muse, mutect2, varscan2
- ATP2B4 | c.2901C>T p.F967= | Silent (SNP) | VAF 46/734 reads (6%) | catalogued as rs531305517; called by muse, mutect2
- C1orf167 | c.2589C>A p.L863= | Silent (SNP) | VAF 31/164 reads (19%) | called by muse, mutect2, varscan2
- CCDC166 | c.999G>T p.R333= | Silent (SNP) | VAF 41/182 reads (23%) | called by muse, mutect2, varscan2
- CCDC166 | c.220C>A p.R74= | Silent (SNP) | VAF 54/189 reads (29%) | catalogued as rs1326426041; called by muse, mutect2, varscan2
- CDX1 | c.102C>A p.A34= | Silent (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- CFAP44 | c.3504G>A p.Q1168= | Silent (SNP) | VAF 14/245 reads (6%) | called by muse, mutect2
- CFAP74 | c.3351C>A p.A1117= | Silent (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2, varscan2
- CIBAR2 | c.843G>C p.V281= | Silent (SNP) | VAF 27/137 reads (20%) | called by muse, mutect2, varscan2
- CLSTN3 | c.270G>T p.L90= | Silent (SNP) | VAF 40/314 reads (13%) | catalogued as rs781710631; called by muse, mutect2, varscan2
- CNIH1 | c.141C>G p.T47= | Silent (SNP) | VAF 24/308 reads (8%) | called by muse, mutect2
- CNTN1 | c.384A>T p.A128= | Silent (SNP) | VAF 58/525 reads (11%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.892C>A p.R298= | Silent (SNP) | VAF 41/558 reads (7%) | called by muse, mutect2
- CROCC | c.2148C>A p.G716= | Silent (SNP) | VAF 21/140 reads (15%) | called by muse, mutect2, varscan2
- CSMD1 | c.7926G>T p.G2642= (on ENST00000520002; = p.G2641= on NM_033225.6) | Silent (SNP) | VAF 17/346 reads (5%) | called by muse, mutect2
- DDX3Y | c.1572G>T p.V524= | Silent (SNP) | VAF 44/311 reads (14%) | called by muse, mutect2, varscan2
- DHX9 | c.606A>G p.Q202= | Silent (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2
- DUXA | c.90C>G p.L30= | Silent (SNP) | VAF 44/396 reads (11%) | called by muse, mutect2, varscan2
- EDN3 | c.486G>T p.V162= | Silent (SNP) | VAF 79/613 reads (13%) | catalogued as rs372385465, COSV61109426; called by muse, mutect2, varscan2
- EDRF1 | c.888C>T p.H296= | Silent (SNP) | VAF 37/209 reads (18%) | called by muse, mutect2, varscan2
- EXOC3L4 | c.696C>A p.G232= | Silent (SNP) | VAF 19/115 reads (17%) | called by muse, mutect2, varscan2
- FAM153B | c.720C>T p.D240= (on ENST00000253490; = p.D163= on NM_001265615.1) | Silent (SNP) | VAF 76/878 reads (9%) | catalogued as COSV53686899; called by muse, mutect2
- GABRA5 | c.504C>A p.T168= | Silent (SNP) | VAF 26/434 reads (6%) | catalogued as COSV59479485; called by muse, mutect2
- GAS7 | c.1155C>T p.R385= (on ENST00000432992 / NM_201433.2; = p.R245= on NM_003644.3) | Silent (SNP) | VAF 112/530 reads (21%) | called by muse, mutect2, varscan2
- HSPA6 | c.1557G>A p.R519= | Silent (SNP) | VAF 25/229 reads (11%) | catalogued as rs758041407; called by muse, mutect2, varscan2
- IGKV3-15 | c.297G>A p.Q99= | Silent (SNP) | VAF 50/1826 reads (3%) | catalogued as rs1213204071; called by muse, mutect2
- IGSF10 | c.4503A>C p.T1501= | Silent (SNP) | VAF 15/198 reads (8%) | called by muse, mutect2
- IL4R | c.708C>T p.G236= | Silent (SNP) | VAF 41/339 reads (12%) | catalogued as rs932697863, COSV99405276; called by muse, mutect2, varscan2
- INSM1 | c.312G>T p.R104= | Silent (SNP) | VAF 21/163 reads (13%) | called by muse, mutect2, varscan2
- KCNA5 | c.1464C>G p.P488= | Silent (SNP) | VAF 26/166 reads (16%) | called by muse, mutect2, varscan2
- KIF26A | c.201C>T p.G67= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV59464838; called by muse, mutect2, varscan2
- KIF26A | c.4929C>A p.P1643= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs778648532; called by muse, mutect2, varscan2
- KIR3DL2 | c.378C>G p.L126= | Silent (SNP) | VAF 79/449 reads (18%) | called by muse, mutect2, varscan2
- LAMA2 | c.3231C>A p.G1077= | Silent (SNP) | VAF 35/604 reads (6%) | catalogued as rs376529091; called by muse, mutect2
- MAP3K13 | c.192C>T p.V64= | Silent (SNP) | VAF 43/192 reads (22%) | called by muse, mutect2, varscan2
- MAPT | c.789C>A p.L263= (on ENST00000262410 / NM_001377265.1; = p.L188= on NM_016835.4) | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- MIA2 | c.1674C>T p.T558= | Silent (SNP) | VAF 30/437 reads (7%) | catalogued as rs747439190, COSV54483029; called by muse, mutect2
- MYO18A | c.5949C>G p.V1983= | Silent (SNP) | VAF 39/354 reads (11%) | called by muse, mutect2, varscan2
- NKX2-1 | c.213G>T p.T71= | Silent (SNP) | VAF 19/178 reads (11%) | catalogued as rs772975871; called by muse, mutect2, varscan2
- OLFM4 | c.753G>T p.V251= | Silent (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2
- OR56A1 | c.660T>C p.S220= | Silent (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- OR6B1 | c.87G>T p.L29= | Silent (SNP) | VAF 22/240 reads (9%) | called by muse, mutect2
- OR6N1 | c.162G>T p.R54= | Silent (SNP) | VAF 18/320 reads (6%) | called by muse, mutect2
- OVCH2 | c.597G>T p.L199= | Silent (SNP) | VAF 12/270 reads (4%) | called by muse, mutect2
- PARD3B | c.1002A>G p.T334= | Silent (SNP) | VAF 34/520 reads (7%) | called by muse, mutect2
- PAX1 | c.792C>A p.G264= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs140128849, COSV101270196, COSV68271594; called by muse, mutect2, varscan2
- PCDH15 | c.5136C>A p.L1712= | Silent (SNP) | VAF 28/239 reads (12%) | called by muse, mutect2, varscan2
- PER3 | c.756C>G p.L252= | Silent (SNP) | VAF 28/294 reads (10%) | called by muse, mutect2
- PIEZO2 | c.5349G>A p.A1783= | Silent (SNP) | VAF 18/372 reads (5%) | catalogued as rs901049706, COSV53290728; called by muse, mutect2
- PLK3 | c.1921C>A p.R641= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as COSV100221237; called by muse, mutect2, varscan2
- PNLIPRP1 | c.780G>T p.L260= | Silent (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- PRDM10 | c.270C>T p.V90= | Silent (SNP) | VAF 78/396 reads (20%) | called by muse, mutect2, varscan2
- RBBP5 | c.291A>T p.S97= | Silent (SNP) | VAF 27/483 reads (6%) | called by muse, mutect2
- RNASE3 | c.138C>T p.N46= | Silent (SNP) | VAF 56/795 reads (7%) | catalogued as rs142084658, COSV58959173; called by muse, mutect2
- ROBO4 | c.1806A>G p.P602= | Silent (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- SF3B4 | c.1071A>G p.P357= | Silent (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- SGCD | c.765G>T p.T255= (on ENST00000435422 / NM_001128209.2; = p.T256= on NM_000337.5) | Silent (SNP) | VAF 38/302 reads (13%) | catalogued as COSV61908199; called by muse, mutect2, varscan2
- SLC9A3R1 | c.765G>C p.L255= | Silent (SNP) | VAF 42/576 reads (7%) | called by muse, mutect2
- SLCO1B1 | c.2052G>T p.G684= | Silent (SNP) | VAF 51/351 reads (15%) | called by muse, mutect2, varscan2
- SP8 | c.957G>T p.P319= (on ENST00000361443 / NM_198956.4; = p.P337= on NM_182700.6) | Silent (SNP) | VAF 21/186 reads (11%) | called by mutect2, varscan2
- SPDYE6 | c.720C>T p.S240= | Silent (SNP) | VAF 73/786 reads (9%) | catalogued as rs781787853; called by muse, mutect2, varscan2
- SSTR4 | c.798C>T p.V266= | Silent (SNP) | VAF 25/248 reads (10%) | catalogued as rs1377665434, COSV54799822; called by muse, mutect2, varscan2
- TDRD15 | c.354G>A p.P118= | Silent (SNP) | VAF 14/220 reads (6%) | catalogued as rs955169656; called by muse, mutect2
- TIGD3 | c.975C>T p.G325= | Silent (SNP) | VAF 26/176 reads (15%) | called by muse, mutect2, varscan2
- TMEM176A | c.105C>A p.T35= | Silent (SNP) | VAF 20/321 reads (6%) | called by muse, mutect2
- TMEM230 | c.237C>T p.A79= | Silent (SNP) | VAF 17/193 reads (9%) | catalogued as rs548325058; called by muse, mutect2
- TOMM40 | c.96G>A p.P32= | Silent (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- TRIM71 | c.261C>A p.L87= | Silent (SNP) | VAF 38/204 reads (19%) | called by muse, mutect2, varscan2
- TRPC5 | c.1545T>G p.L515= | Silent (SNP) | VAF 32/274 reads (12%) | called by muse, mutect2, varscan2
- TRPV6 | c.1161C>T p.C387= | Silent (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- VIRMA | c.3474C>T p.L1158= | Silent (SNP) | VAF 26/538 reads (5%) | catalogued as COSV52583627; called by muse, mutect2
- VRTN | c.642G>A p.V214= | Silent (SNP) | VAF 31/253 reads (12%) | called by muse, mutect2, varscan2
- VXN | c.591G>A p.V197= | Silent (SNP) | VAF 31/151 reads (21%) | called by muse, mutect2, varscan2
- WASHC2C | c.1398C>G p.P466= | Silent (SNP) | VAF 35/769 reads (5%) | catalogued as rs1564748157; called by muse, mutect2
- ZIM2 | c.636G>T p.L212= | Silent (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- ZNF397 | c.810A>G p.T270= | Silent (SNP) | VAF 32/188 reads (17%) | called by muse, mutect2, varscan2
- ZNF729 | c.1170A>G p.K390= | Silent (SNP) | VAF 50/396 reads (13%) | catalogued as rs1422427743; called by muse, mutect2, varscan2
- ZSWIM3 | c.1890C>T p.L630= | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as rs1009935259, COSV54849799; called by muse, mutect2, varscan2
- ABI3BP | c.1577-3496G>T | Intron (SNP) | VAF 80/426 reads (19%) | called by muse, mutect2, varscan2
- AC099552.1 | n.247G>T | RNA (SNP) | VAF 29/466 reads (6%) | called by muse, mutect2
- AC107023.1 | n.25+10050C>A | Intron (SNP) | VAF 12/116 reads (10%) | called by muse, varscan2
- AC116655.1 | n.207A>T | RNA (SNP) | VAF 20/221 reads (9%) | called by muse, mutect2, varscan2
- ADA | c.362+12G>A | Intron (SNP) | VAF 71/486 reads (15%) | catalogued as rs1192108000; called by muse, mutect2, varscan2
- ALG3 | chr3:184248990 C>G | 5'Flank (SNP) | VAF 83/288 reads (29%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500570 G>A | 5'Flank (SNP) | VAF 12/317 reads (4%) | called by muse, mutect2
- ATL3 | chr11:63671701 G>C | 5'Flank (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- C15orf54 | n.706C>G | RNA (SNP) | VAF 42/334 reads (13%) | called by muse, mutect2, varscan2
- CATSPER2 | c.-87+13G>T | Intron (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- CDON | c.-6G>T | 5'UTR (SNP) | VAF 34/840 reads (4%) | called by muse, mutect2
- CFAP61 | c.2503+2298A>G | Intron (SNP) | VAF 49/497 reads (10%) | called by muse, mutect2
- COL1A2 | c.2296-46C>A | Intron (SNP) | VAF 74/600 reads (12%) | called by muse, mutect2, varscan2
- COMMD6 | c.54+213A>C | Intron (SNP) | VAF 78/495 reads (16%) | called by muse, mutect2, varscan2
- CREB1 | c.881+4501A>T | Intron (SNP) | VAF 20/200 reads (10%) | called by muse, mutect2
- DST | c.4297-1365G>C | Intron (SNP) | VAF 38/596 reads (6%) | called by muse, mutect2
- EYS | c.1767-8486G>A | Intron (SNP) | VAF 60/385 reads (16%) | called by muse, mutect2, varscan2
- FAM124B | c.732+589C>A | Intron (SNP) | VAF 42/613 reads (7%) | called by muse, mutect2
- FRYL | c.-81+3586G>C | Intron (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- GABRG3 | c.574+21283C>A | Intron (SNP) | VAF 53/354 reads (15%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | chr7:73269225 G>C | 5'Flank (SNP) | VAF 30/668 reads (4%) | catalogued as rs782666696; called by muse, mutect2
- MFRP | chr11:119346164 G>T | 5'Flank (SNP) | VAF 91/371 reads (25%) | called by muse, mutect2, varscan2
- MKRN1 | c.186-1270A>G | Intron (SNP) | VAF 37/371 reads (10%) | catalogued as rs1171790454; called by muse, mutect2
- MTSS1 | c.460+4504C>G | Intron (SNP) | VAF 35/440 reads (8%) | called by muse, mutect2
- MUCL3 | c.947-498G>A | Intron (SNP) | VAF 20/210 reads (10%) | catalogued as COSV58518121; called by muse, mutect2
- NAV3 | c.2024-12792G>A | Intron (SNP) | VAF 73/548 reads (13%) | called by muse, mutect2, varscan2
- NLGN1 | c.494-7381T>G | Intron (SNP) | VAF 37/261 reads (14%) | catalogued as rs894795942; called by muse, mutect2, varscan2
- NLRP7 | c.-67G>C | 5'UTR (SNP) | VAF 47/306 reads (15%) | catalogued as rs1469833838; called by muse, mutect2, varscan2
- NLRP7 | c.-68G>T | 5'UTR (SNP) | VAF 49/314 reads (16%) | called by muse, mutect2, varscan2
- NT5C3A | c.-29del | 5'UTR (DEL) | VAF 39/356 reads (11%) | called by mutect2, pindel, varscan2
- OR4K17 | c.-17G>A | 5'UTR (SNP) | VAF 27/211 reads (13%) | catalogued as rs776703913; called by muse, mutect2, varscan2
- PHGDH | c.290+31G>T | Intron (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2
- PKD2 | c.710-44G>A | Intron (SNP) | VAF 23/328 reads (7%) | called by muse, mutect2
- PLEC | c.523+4970C>T | Intron (SNP) | VAF 39/165 reads (24%) | catalogued as rs782734530; called by muse, mutect2, varscan2
- RAB3IP | c.1279-11A>C | Intron (SNP) | VAF 32/303 reads (11%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.4113G>A | RNA (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- SCP2D1 | chr20:18809928 G>T | 5'Flank (SNP) | VAF 38/549 reads (7%) | called by muse, mutect2
- SEPTIN9 | c.1625+26_1625+50del | Intron (DEL) | VAF 26/189 reads (14%) | called by mutect2, pindel
- SLC47A1P2 | n.415G>C | RNA (SNP) | VAF 15/279 reads (5%) | called by muse, mutect2
- SLC51A | c.-93C>T | 5'UTR (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- SNORD115-31 | n.22T>C | RNA (SNP) | VAF 28/370 reads (8%) | called by muse, mutect2
- SNORD116-22 | chr15:25092100 A>T | 3'Flank (SNP) | VAF 48/326 reads (15%) | called by muse, mutect2, varscan2
- TIAM2 | c.3168+5738C>A | Intron (SNP) | VAF 9/206 reads (4%) | called by muse, mutect2
- TMEM30A-DT | n.296+10627G>C | Intron (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- TNNI3K | c.1772+5183G>T | Intron (SNP) | VAF 40/476 reads (8%) | called by muse, mutect2
- TRIM66 | c.2396-14G>T | Intron (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- TTN | c.10360+5467C>A | Intron (SNP) | VAF 34/594 reads (6%) | catalogued as COSV100621490; called by muse, mutect2
- UBE2N | c.-35G>T | 5'UTR (SNP) | VAF 22/129 reads (17%) | called by muse, mutect2, varscan2
- USP15 | c.683+2371A>C | Intron (SNP) | VAF 23/279 reads (8%) | called by muse, mutect2
- XIST | n.8407G>T | RNA (SNP) | VAF 8/197 reads (4%) | called by muse, mutect2
- ZIC4 | c.*47C>A | 3'UTR (SNP) | VAF 20/195 reads (10%) | catalogued as rs945666747, COSV67171488; called by muse, mutect2, varscan2
